CCDI case PBCHZW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/19bd7da1-bf98-4115-a172-7d692cc6f830

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dermatofibrosarcoma protuberans, NOS: ICD-O-3 morphology code: 8832/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 2.4 years (864 days).

Biospecimens (3 samples)
- Samples 0DSI7E, 0DSI8G (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSI85: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
